Somatic mutation profile of tumor specimen TCGA-21-1071-01A (aliquot TCGA-21-1071-01A-01W-0782-08) from TCGA case TCGA-21-1071, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.1 years (24,515 days).
Specimen TCGA-21-1071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9da698b7-cc27-4c8f-9701-b8a7f5a52253.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1071-11A (Solid Tissue Normal), aliquot TCGA-21-1071-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff8b4046-c315-4ed8-8b16-c480341bc4ee

The open-access MAF lists 188 somatic variants for this specimen: 146 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 38, Splice Site 4, Nonsense Mutation 4, Frame Shift Del 4, Intron 2, 3'Flank 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.239C>A p.T80K | Missense Mutation (SNP) | VAF 98/184 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553487947, COSV67960012, COSV67960020, COSV67960088; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 50/115 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.1284G>T p.L428F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV70025996; called by muse, mutect2
- ADAMTS18 | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51399139, COSV51420022; called by muse, mutect2, varscan2
- ADCY1 | c.3155A>T p.Y1052F | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV52030442; called by muse, mutect2, varscan2
- ADGRL3 | c.3656C>G p.S1219C (on ENST00000506720 / NM_001322402.2; = p.S1151C on NM_015236.6) | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV72229476; called by muse, mutect2, varscan2
- ADGRV1 | c.11620A>G p.I3874V | Missense Mutation (SNP) | VAF 90/701 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs770916018, COSV67978977; called by muse, mutect2, varscan2
- ALMS1 | c.8089C>T p.H2697Y | Missense Mutation (SNP) | VAF 122/953 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs956487104, COSV52503299; called by muse, mutect2, varscan2
- ANKAR | c.1747T>G p.L583V | Missense Mutation (SNP) | VAF 179/346 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55609709; called by muse, mutect2, varscan2
- ARHGEF2 | c.647C>G p.S216C (on ENST00000361247 / NM_001162383.2; = p.S188C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58106830; called by muse, mutect2, varscan2
- ATF6 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs868465685, COSV100909341; called by muse, mutect2
- BCL2A1 | c.401T>G p.I134R | Missense Mutation (SNP) | VAF 25/442 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51212896, COSV99144359; called by muse, mutect2
- BMS1 | c.792G>T p.L264F | Missense Mutation (SNP) | VAF 38/467 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65732914; called by muse, mutect2
- BRF2 | c.115del p.V39Sfs*15 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs757254105; called by mutect2, pindel, varscan2
- BRPF1 | c.3553C>T p.R1185C | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100115492, COSV57351437; called by muse, mutect2
- C1QTNF6 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV55395746, COSV55396920; called by muse, mutect2, varscan2
- C1orf74 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 38/655 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.536); catalogued as COSV50550411; called by muse, mutect2
- CASD1 | c.1444A>G p.K482E | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51970784; called by muse, mutect2
- CCN3 | c.705T>G p.C235W | Missense Mutation (SNP) | VAF 42/477 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52383113; called by muse, mutect2
- CD300LB | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 58/403 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58725110, COSV58725123; called by muse, mutect2, varscan2
- CPS1 | c.3374C>A p.P1125H | Missense Mutation (SNP) | VAF 124/313 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51802653; called by muse, varscan2
- CRB1 | c.3307G>C p.G1103R | Missense Mutation (SNP) | VAF 80/124 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as CM040718, CM057655, COSV100958048, COSV66328782, COSV66330317; called by muse, mutect2, varscan2
- CRY1 | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1361980808, COSV50481114; called by muse, mutect2, varscan2
- CRYBA4 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61321326; called by muse, mutect2, varscan2
- CSMD3 | c.9872G>A p.C3291Y (on ENST00000297405 / NM_001363185.1; = p.C3122Y on NM_052900.3) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1330141465, COSV52107992, COSV52358454; called by muse, varscan2
- CTNNA3 | c.1990C>A p.Q664K | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.973); catalogued as COSV65524407; called by muse, mutect2
- CYB5R4 | c.549A>G p.I183M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs1386300386, COSV63750150; called by muse, mutect2, varscan2
- DCAF4L2 | c.1002G>C p.Q334H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100150553; called by muse, mutect2
- DNAH2 | c.5288T>G p.F1763C | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66716643; called by muse, mutect2, varscan2
- DNAH7 | c.12026A>C p.E4009A | Missense Mutation (SNP) | VAF 151/326 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as COSV56752926; called by muse, mutect2, varscan2
- DNM2 | c.2222C>A p.T741N (on ENST00000355667 / NM_001005360.3; = p.T737N on NM_004945.3) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV53033158; called by muse, mutect2, varscan2
- DOCK4 | c.2915G>T p.R972L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs750882888, COSV70233780; called by muse, mutect2, varscan2
- DPEP2 | c.1369C>G p.P457A | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV52053842; called by muse, mutect2
- DPP10 | c.230A>T p.K77I | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV59666066; called by muse, mutect2
- DYSF | c.4133C>T p.P1378L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50270045, COSV99249124; called by muse, mutect2, varscan2
- EMC2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs749642246, COSV55207965; called by muse, mutect2, varscan2
- EML5 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 109/943 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); catalogued as COSV61342099; called by muse, mutect2, varscan2
- F2R | c.932C>A p.A311D | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59928486; called by muse, mutect2
- FANCB | c.455T>G p.F152C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV60758904; called by muse, mutect2, varscan2
- FBN2 | c.2317G>C p.A773P | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52494356; called by muse, mutect2, varscan2
- FLG2 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 62/1318 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.748); catalogued as COSV66166783; called by muse, mutect2
- G6PC | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 140/532 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV53830166, COSV53830614; called by muse, mutect2, varscan2
- GAB1 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1476488595, COSV53754617; called by muse, mutect2, varscan2
- GABPA | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.082); catalogued as COSV61395448; called by muse, mutect2, varscan2
- GJA10 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65354801; called by muse, mutect2
- GLI1 | c.2458T>G p.C820G | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.986); catalogued as COSV99953755; called by mutect2, varscan2
- GLYATL1 | c.781C>T p.P261S (on ENST00000317391 / NM_001354699.1; = p.P292S on NM_080661.4) | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55607273; called by muse, mutect2, varscan2
- GNPDA2 | c.495T>G p.D165E | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.024); catalogued as COSV54946055; called by muse, mutect2, varscan2
- GOT2 | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55330804; called by muse, mutect2, varscan2
- GPR152 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV100351542, COSV56885123; called by muse, mutect2, varscan2
- H2BC13 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV62440465; called by muse, mutect2, varscan2
- HSPA12A | c.620G>A p.W207* | Nonsense Mutation (SNP) | VAF 118/323 reads (37%) | catalogued as COSV65020884; called by muse, mutect2, varscan2
- HTT | c.2257A>G p.I753V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61857785; called by muse, mutect2, varscan2
- IGSF11 | c.653C>G p.S218C (on ENST00000393775 / NM_001015887.3; = p.S217C on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61165876; called by muse, mutect2
- INVS | c.1105C>A p.H369N | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV52438315; called by muse, mutect2
- IQGAP2 | c.2840T>C p.I947T | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57168296; called by muse, mutect2, varscan2
- IQGAP3 | c.2674G>C p.E892Q | Missense Mutation (SNP) | VAF 187/292 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs768517691, COSV63249522; called by muse, mutect2, varscan2
- ITPRID1 | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.069); catalogued as COSV60070448; called by muse, mutect2, varscan2
- KCNH4 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1365185558, COSV52915450; called by muse, mutect2, varscan2
- KCNT2 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV54065078, COSV99657109; called by muse, mutect2
- KIF24 | c.800A>C p.Q267P | Missense Mutation (SNP) | VAF 69/494 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61453285; called by muse, mutect2, varscan2
- KMT5B | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV58563864; called by muse, mutect2, varscan2
- LILRA6 | c.845C>A p.T282N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV54429825; called by muse, mutect2, varscan2
- LPCAT3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as rs782492797, COSV54644836; called by muse, mutect2, varscan2
- LRP4 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs781681900, COSV66134090; called by muse, mutect2, varscan2
- LRRC7 | c.2297C>A p.P766Q (on ENST00000651989 / NM_001370785.2; = p.P733Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50413157; called by muse, mutect2, varscan2
- LYAR | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1299597889, COSV58642192; called by muse, mutect2, varscan2
- LYNX1 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100235640, COSV59988060; called by muse, mutect2, varscan2
- MAB21L1 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV59761902; called by muse, mutect2, varscan2
- MB21D2 | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV101165176, COSV66661748; called by muse, mutect2
- MED23 | c.417A>C p.K139N | Missense Mutation (SNP) | VAF 82/130 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV63430296; called by muse, mutect2, varscan2
- MET | c.3287C>G p.T1096S | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs45592846, COSV59257129; called by muse, mutect2
- MIS18BP1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100172748, COSV60369211; called by muse, mutect2, varscan2
- MNDA | c.420C>A p.N140K | Missense Mutation (SNP) | VAF 29/391 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV63739973; called by muse, mutect2
- MTRR | c.8C>G p.A3G | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV52941829, COSV52948066; called by muse, mutect2, varscan2
- MYBPH | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as COSV55137187; called by muse, mutect2, varscan2
- NID2 | c.2908C>A p.L970M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.657); catalogued as COSV53493228; called by mutect2, varscan2
- NRXN2 | c.3071C>A p.T1024K | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs757534789, COSV55447700; called by muse, mutect2, varscan2
- OIT3 | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61825097; called by muse, mutect2, varscan2
- OR10G7 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57865675; called by muse, mutect2
- OR4C13 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 66/532 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV73648638; called by muse, mutect2, varscan2
- OR4F15 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 70/717 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59968285; called by muse, mutect2
- OR52W1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60950455; called by muse, mutect2, varscan2
- OR8H1 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57293080; called by muse, mutect2, varscan2
- PCDHGA3 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 80/213 reads (38%) | catalogued as COSV53902853, COSV54066637; called by muse, mutect2, varscan2
- PCLO | c.14342A>T p.Q4781L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61617163; called by muse, mutect2, varscan2
- PCLO | c.6560C>T p.S2187F | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV61617165; called by muse, mutect2
- PCM1 | c.840T>A p.H280Q | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61514842; called by muse, mutect2, varscan2
- PDE1A | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV59515074; called by muse, mutect2, varscan2
- PILRA | c.790-1G>C p.X264_splice | Splice Site (SNP) | VAF 56/538 reads (10%) | catalogued as COSV52199255; called by muse, mutect2
- PPP3CA | c.1242-1G>T p.X414_splice | Splice Site (SNP) | VAF 29/110 reads (26%) | catalogued as COSV59919803; called by muse, mutect2, varscan2
- PSG5 | c.266A>T p.N89I | Missense Mutation (SNP) | VAF 696/1090 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745773766, COSV61653557; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3115G>T p.V1039L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as COSV54758308; called by muse, mutect2, varscan2
- RALGAPB | c.195G>T p.W65C | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53434574; called by muse, mutect2
- RNF114 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54868754; called by muse, mutect2, varscan2
- ROBO2 | c.706G>C p.V236L | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.362); catalogued as COSV59898147; called by muse, mutect2, varscan2
- RP1 | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV55110588; called by muse, mutect2, varscan2
- RP1L1 | c.6591G>T p.E2197D | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV66751966; called by muse, mutect2, varscan2
- RP1L1 | c.2387C>A p.A796D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV66751968; called by mutect2, varscan2
- RSAD1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.037); catalogued as COSV51954752, COSV99364111; called by muse, mutect2, varscan2
- RYR2 | c.8814G>C p.Q2938H | Missense Mutation (SNP) | VAF 110/196 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV63663883, COSV99053505; called by muse, mutect2, varscan2
- SCG5 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 49/580 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55705262; called by muse, mutect2
- SETD1A | c.4838G>A p.R1613H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs765554192, COSV52679658; called by muse, mutect2, varscan2
- SETD5 | c.2692G>A p.A898T | Missense Mutation (SNP) | VAF 240/532 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs774430004, COSV56707677; called by muse, mutect2, varscan2
- SGK2 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.309); catalogued as COSV58312161; called by muse, mutect2, varscan2
- SKAP2 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61721550; called by muse, mutect2, varscan2
- SLC15A2 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 184/1056 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs1339657136, COSV55196096; called by muse, mutect2, varscan2
- SLC25A33 | c.57-2A>C p.X19_splice | Splice Site (SNP) | VAF 26/223 reads (12%) | catalogued as COSV57019166; called by muse, mutect2, varscan2
- SLC27A2 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.633); catalogued as COSV51057522; called by muse, mutect2
- SLC35G1 | c.844G>A p.G282R (on ENST00000427197 / NM_001134658.3; = p.G281R on NM_153226.4) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV65055058, COSV65055726; called by muse, mutect2, varscan2
- SLITRK2 | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59423265, COSV59428303; called by muse, mutect2, varscan2
- SNX20 | c.170C>A p.T57K | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56056681; called by muse, mutect2, varscan2
- SPHKAP | c.36C>A p.N12K | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60869216; called by muse, mutect2
- SSH2 | c.2935C>A p.Q979K | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52166885; called by muse, mutect2, varscan2
- STAP1 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99609193; called by muse, mutect2, varscan2
- SUPT20H | c.899T>A p.L300* (on ENST00000350612 / NM_001014286.3; = p.L301* on NM_017569.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as COSV62246854; called by muse, mutect2, varscan2
- SYCP2 | c.3619C>T p.L1207F | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1319213908, COSV62765975; called by muse, mutect2, varscan2
- TASP1 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as COSV61811482; called by muse, mutect2, varscan2
- TBK1 | c.813-1G>T p.X271_splice | Splice Site (SNP) | VAF 46/137 reads (34%) | catalogued as COSV100538042; called by muse, mutect2, varscan2
- TENM3 | c.42G>C p.K14N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1390946372, COSV69299825; called by muse, mutect2, varscan2
- TMC5 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs774931297, COSV66864553; called by muse, mutect2
- TMEM181 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs200013277; called by muse, mutect2, varscan2
- TMEM87B | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); catalogued as rs1415117062, COSV51712905; called by muse, varscan2
- TMTC3 | c.2637C>A p.D879E | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV57122434, COSV99898802; called by muse, mutect2, varscan2
- TMTC3 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199847201, COSV57122444; called by muse, mutect2, varscan2
- TREML2 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.261); catalogued as COSV101530194, COSV72439024; called by muse, mutect2, varscan2
- TTBK1 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV52488358, COSV99445067; called by muse, mutect2, varscan2
- TTPA | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV52645847, COSV99478420; called by muse, mutect2, varscan2
- UNC13A | c.2081C>A p.T694K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53188794; called by muse, mutect2
- WNK1 | c.3758C>T p.S1253F (on ENST00000315939 / NM_018979.4; = p.S1006F on NM_014823.3) | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60026017; called by muse, mutect2, varscan2
- WNK3 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV63612192; called by muse, mutect2, varscan2
- ZDBF2 | c.3575A>G p.N1192S | Missense Mutation (SNP) | VAF 156/282 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV65622078; called by muse, mutect2, varscan2
- ZFAND1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV55106720; called by muse, mutect2, varscan2
- ZFHX4 | c.7135C>A p.P2379T | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51449413; called by muse, mutect2, varscan2
- ZNF230 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 115/216 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71273235; called by muse, mutect2, varscan2
- ZNF311 | c.743A>C p.E248A | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.042); catalogued as COSV65852856; called by muse, mutect2, varscan2
- ZNF804B | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60817105; called by muse, mutect2
- ALMS1 | c.7795del p.R2599Dfs*14 | Frame Shift Del (DEL) | VAF 83/381 reads (22%) | called by mutect2, pindel, varscan2
- ASTN1 | c.2458C>A p.L820I | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2
- CDCA2 | c.2791G>A p.G931R | Missense Mutation (SNP) | VAF 68/902 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.15); called by muse, mutect2
- CHSY1 | c.2263C>G p.L755V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD2 | c.2629C>T p.Q877* | Nonsense Mutation (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- KMT2D | c.12625_12626del p.P4209Tfs*124 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- PRX | c.3785_3818del p.E1262Afs*109 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | called by mutect2, pindel
- SOGA1 | c.2515G>C p.E839Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF250 | c.1548C>A p.F516L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRL4 | c.711C>T p.S237= | Silent (SNP) | VAF 43/338 reads (13%) | catalogued as COSV66059504; called by muse, mutect2, varscan2
- CA3 | c.441G>T p.L147= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV53409234; called by muse, mutect2, varscan2
- CAMKMT | c.366A>T p.T122= | Silent (SNP) | VAF 96/191 reads (50%) | catalogued as COSV65923580; called by muse, mutect2, varscan2
- CASK | c.744T>C p.S248= | Silent (SNP) | VAF 26/307 reads (8%) | called by muse, mutect2
- CDH10 | c.534T>C p.S178= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as rs1231628581, COSV52571627, COSV52588846; called by muse, mutect2
- CHD5 | c.4161G>A p.P1387= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as rs773893368, COSV52408168; called by muse, mutect2, varscan2
- CLP1 | c.978C>T p.I326= | Silent (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- ERCC6L | c.960C>A p.I320= | Silent (SNP) | VAF 66/95 reads (69%) | catalogued as COSV57819451; called by muse, mutect2, varscan2
- FCHSD2 | c.648G>A p.A216= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as rs772728306; called by muse, mutect2
- FHL5 | c.408T>C p.P136= | Silent (SNP) | VAF 73/164 reads (45%) | catalogued as COSV58735263; called by muse, mutect2, varscan2
- GABRG2 | c.90G>T p.L30= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs115976622, COSV62715630; called by muse, mutect2
- GHSR | c.822C>A p.L274= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- GPC4 | c.1479T>C p.S493= | Silent (SNP) | VAF 233/363 reads (64%) | catalogued as COSV63696939; called by muse, mutect2, varscan2
- HAPLN1 | c.453G>T p.V151= | Silent (SNP) | VAF 207/473 reads (44%) | catalogued as COSV57145540; called by muse, mutect2, varscan2
- KRT33B | c.246G>A p.A82= | Silent (SNP) | VAF 12/197 reads (6%) | catalogued as rs201559637, COSV52440218; called by muse, mutect2
- MAG | c.1722G>A p.E574= | Silent (SNP) | VAF 74/217 reads (34%) | catalogued as COSV62699040; called by muse, mutect2, varscan2
- MUC16 | c.30120G>A p.P10040= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as rs562057777, COSV67446596; called by muse, mutect2, varscan2
- MYOT | c.939C>A p.V313= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99524787; called by muse, mutect2, varscan2
- OR51L1 | c.648A>T p.I216= | Silent (SNP) | VAF 58/163 reads (36%) | catalogued as COSV58623945; called by muse, mutect2, varscan2
- OR5B12 | c.870G>C p.L290= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as rs1182994357, COSV56904024; called by muse, mutect2
- PCDHB7 | c.2257C>T p.L753= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV50754596; called by muse, mutect2, varscan2
- PHF10 | c.732A>C p.P244= | Silent (SNP) | VAF 48/227 reads (21%) | catalogued as COSV59321085; called by muse, mutect2, varscan2
- PITX2 | c.943C>A p.R315= (on ENST00000354925 / NM_001204397.1; = p.R322= on NM_000325.6) | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100146222, COSV100146291, COSV60741638; called by muse, mutect2, varscan2
- PLD2 | c.1776C>T p.L592= | Silent (SNP) | VAF 122/341 reads (36%) | catalogued as COSV54003590; called by muse, mutect2, varscan2
- PROP1 | c.198G>A p.P66= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as rs769315766, COSV57644591; called by muse, mutect2, varscan2
- REST | c.76C>T p.L26= | Silent (SNP) | VAF 15/64 reads (23%) | called by mutect2, varscan2
- SLC25A43 | c.675G>A p.V225= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV54216914; called by muse, mutect2, varscan2
- SLC26A4 | c.1752G>A p.A584= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs771015634, COSV55914542; ClinVar: likely benign; called by muse, varscan2
- SLC36A2 | c.1152C>T p.S384= | Silent (SNP) | VAF 30/426 reads (7%) | catalogued as COSV58862147; called by muse, mutect2
- SMAD4 | c.1632G>T p.P544= | Silent (SNP) | VAF 21/210 reads (10%) | catalogued as rs549489716, COSV61684929, COSV61694171; called by muse, mutect2
- TESK1 | c.930C>T p.H310= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as rs1478633366, COSV52410279; called by muse, mutect2, varscan2
- TET2 | c.2157G>A p.L719= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- THBS4 | c.1224G>A p.P408= | Silent (SNP) | VAF 60/251 reads (24%) | catalogued as rs548126974, COSV63467797; called by muse, varscan2
- TTC24 | c.1566C>T p.I522= | Silent (SNP) | VAF 10/264 reads (4%) | catalogued as rs1278672872; called by muse, mutect2
- UNC13C | c.372G>A p.E124= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV52845555; called by muse, mutect2, varscan2
- UNC5D | c.219C>G p.L73= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV54771463; called by muse, mutect2, varscan2
- ZFAND2A | c.114A>G p.P38= | Silent (SNP) | VAF 126/542 reads (23%) | catalogued as rs1002227737, COSV57179941; called by muse, varscan2
- ZFAT | c.1206G>A p.L402= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV64734700; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506380 T>C | 3'Flank (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- GGNBP1 | n.846+849C>A | Intron (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2
- PNCK | c.539-41G>A | Intron (SNP) | VAF 23/32 reads (72%) | catalogued as rs149305071, COSV100562205; called by muse, mutect2, varscan2
- PYY3 | n.191G>A | RNA (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
